Somatic mutation profile of tumor specimen C3L-08245-01 (aliquot CPT0485640007) from CPTAC case C3L-08245, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 77.0 years (28,133 days).
Specimen C3L-08245-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Fundus Of Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 61d75f0b-05de-429a-af3f-9c9a451e4035.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-08245-32 (Blood Derived Normal), aliquot CPT0485790003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3f29ce27-8d77-43e8-92a7-c3305c96c9ea

The open-access MAF lists 303 somatic variants for this specimen: 225 protein-altering or splice-affecting, 64 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 195, Silent 64, Frame Shift Del 13, Nonsense Mutation 11, Intron 7, In Frame Del 6, 5'Flank 2, 5'UTR 2, 3'UTR 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.949C>T p.Q317* | Nonsense Mutation (SNP) | VAF 196/342 reads (57%) | hotspot (GDC flag); catalogued as rs764735889, COSV52685086, COSV53209009; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ABCA8 | c.781C>T p.R261W | Missense Mutation (SNP) | VAF 41/182 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs200821432, COSV52204923; called by mutect2, varscan2
- ABCB9 | c.518C>T p.T173M | Missense Mutation (SNP) | VAF 149/578 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); catalogued as rs114398803; called by mutect2, varscan2
- ABCD2 | c.2041G>A p.G681R | Missense Mutation (SNP) | VAF 66/306 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58054526; called by mutect2, varscan2
- ADCYAP1R1 | c.1061C>A p.S354Y | Missense Mutation (SNP) | VAF 82/286 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58445284; called by mutect2, varscan2
- ANKRD29 | c.836C>A p.P279Q | Missense Mutation (SNP) | VAF 62/528 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99409334; called by mutect2, varscan2
- ANKRD29 | c.835C>A p.P279T | Missense Mutation (SNP) | VAF 62/526 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1334834991, COSV52426440; called by mutect2, varscan2
- ANKRD52 | c.845C>A p.S282Y | Missense Mutation (SNP) | VAF 127/403 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57283680; called by mutect2, varscan2
- ARHGAP25 | c.1421C>T p.S474F (on ENST00000409202 / NM_001007231.3; = p.S466F on NM_014882.3) | Missense Mutation (SNP) | VAF 122/592 reads (21%) | SIFT tolerated (0.6); PolyPhen benign (0.056); catalogued as COSV54909203; called by mutect2, varscan2
- ASIC4 | c.586T>G p.Y196D | Missense Mutation (SNP) | VAF 102/282 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV61732561; called by mutect2, varscan2
- ATP8B2 | c.3047A>G p.D1016G (on ENST00000672630; = p.D983G on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 112/494 reads (23%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.897); catalogued as rs1280344828; called by mutect2, varscan2
- BECN2 | c.816G>T p.L272F | Missense Mutation (SNP) | VAF 117/743 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs896745939; called by mutect2, varscan2
- C11orf95 | c.1397C>G p.T466R | Missense Mutation (SNP) | VAF 145/683 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV58032727; called by mutect2, varscan2
- C7 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 46/288 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as rs755950201, COSV100495266, COSV57482404; called by mutect2, varscan2
- CACNB2 | c.379G>A p.A127T (on ENST00000324631 / NM_201596.3; = p.A72T on NM_000724.4) | Missense Mutation (SNP) | VAF 84/294 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.25); catalogued as rs1347573099; called by mutect2, varscan2
- CCDC168 | c.14459C>T p.P4820L | Missense Mutation (SNP) | VAF 106/456 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.937); catalogued as rs1008997244; called by mutect2, varscan2
- CD163 | c.2358G>A p.M786I | Missense Mutation (SNP) | VAF 100/392 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV63131154; called by mutect2, varscan2
- CDC16 | c.821C>T p.T274M | Missense Mutation (SNP) | VAF 63/278 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.4); catalogued as rs779539760, COSV99372944; called by mutect2, varscan2
- CDH6 | c.1453G>A p.A485T | Missense Mutation (SNP) | VAF 105/369 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.83); catalogued as rs769078251, COSV99418462; called by mutect2, varscan2
- CMAS | c.536G>A p.R179Q | Missense Mutation (SNP) | VAF 46/220 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1232782429, COSV57557202; called by mutect2, varscan2
- CNTN4 | c.496C>T p.Q166* | Nonsense Mutation (SNP) | VAF 64/287 reads (22%) | catalogued as COSV61881672; called by mutect2, varscan2
- COL6A3 | c.1904C>G p.S635* | Nonsense Mutation (SNP) | VAF 55/294 reads (19%) | catalogued as COSV55104800; called by mutect2, varscan2
- COL7A1 | c.5500G>A p.E1834K | Missense Mutation (SNP) | VAF 114/252 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); catalogued as rs750841023; called by mutect2, varscan2
- CPZ | c.742C>A p.H248N (on ENST00000360986 / NM_001014447.3; = p.H237N on NM_003652.3) | Missense Mutation (SNP) | VAF 88/502 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59921973; called by mutect2, varscan2
- DACH1 | c.1876C>G p.Q626E (on ENST00000619232 / NM_001366712.1; = p.Q372E on NM_004392.6) | Missense Mutation (SNP) | VAF 90/202 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.542); catalogued as COSV100499592; called by mutect2, varscan2
- DSC1 | c.1792C>G p.P598A | Missense Mutation (SNP) | VAF 134/323 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV57152165; called by mutect2, varscan2
- DSCAM | c.1001C>T p.S334F | Missense Mutation (SNP) | VAF 150/462 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as rs1451608585, COSV101261531; called by mutect2, varscan2
- EEF1E1 | c.314A>G p.K105R | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.927); catalogued as rs770434382; called by mutect2, varscan2
- FAM186A | c.170C>A p.A57E | Missense Mutation (SNP) | VAF 73/184 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV53325434; called by mutect2, varscan2
- FANCM | c.3613G>A p.D1205N | Missense Mutation (SNP) | VAF 56/178 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs936653683; called by mutect2, varscan2
- FER1L5 | c.419C>T p.T140M | Missense Mutation (SNP) | VAF 88/325 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs760894128, COSV70070106; called by mutect2, varscan2
- GABRQ | c.1456G>A p.V486I | Missense Mutation (SNP) | VAF 158/408 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV64782181; called by mutect2, varscan2
- GNAO1 | c.865C>G p.P289A | Missense Mutation (SNP) | VAF 66/315 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as rs768674142; called by mutect2, varscan2
- GRAMD1B | c.672C>A p.N224K | Missense Mutation (SNP) | VAF 102/372 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV59210491; called by mutect2, varscan2
- GRID2IP | c.85G>A p.V29I | Missense Mutation (SNP) | VAF 191/657 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs1392249890, COSV71849881; called by mutect2, varscan2
- HERC1 | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 108/725 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as rs773817695; called by mutect2, varscan2
- HTR1F | c.864A>C p.E288D | Missense Mutation (SNP) | VAF 79/244 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100138077; called by mutect2, varscan2
- HTR5A | c.354C>G p.I118M | Missense Mutation (SNP) | VAF 266/906 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV55280956; called by mutect2, varscan2
- INPP5J | c.1162C>T p.L388F | Missense Mutation (SNP) | VAF 160/550 reads (29%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV58514042; called by mutect2, varscan2
- ITIH1 | c.2035G>A p.V679M | Missense Mutation (SNP) | VAF 78/194 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs761089193; called by mutect2, varscan2
- KATNBL1 | c.827G>T p.W276L | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1419021063; called by mutect2, varscan2
- KIF26B | c.2467C>T p.R823C | Missense Mutation (SNP) | VAF 155/508 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs775116283, COSV100833076; called by mutect2, varscan2
- LAMA1 | c.691A>G p.I231V | Missense Mutation (SNP) | VAF 156/420 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs754973098; called by mutect2, varscan2
- LUZP1 | c.1186C>T p.Q396* | Nonsense Mutation (SNP) | VAF 44/298 reads (15%) | catalogued as COSV100035625; called by mutect2, varscan2
- MMP28 | c.1489A>G p.T497A | Missense Mutation (SNP) | VAF 164/679 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772206617; called by mutect2, varscan2
- MUC4 | c.5213C>T p.S1738F | Missense Mutation (SNP) | VAF 182/1416 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.496); catalogued as COSV62154297; called by mutect2, varscan2
- MUC6 | c.6387_6389del p.S2130del | In Frame Del (DEL) | VAF 297/495 reads (60%) | catalogued as rs765184193; called by pindel, varscan2
- NACAD | c.3404C>G p.P1135R | Missense Mutation (SNP) | VAF 174/567 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.599); catalogued as COSV101512138; called by mutect2, varscan2
- NKX2-4 | c.624C>G p.F208L | Missense Mutation (SNP) | VAF 136/618 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV61085482; called by mutect2, varscan2
- NOTCH1 | c.5780C>T p.T1927M | Missense Mutation (SNP) | VAF 206/796 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1554826860, COSV53044875; ClinVar: uncertain significance; called by mutect2, varscan2
- OR10A4 | c.133C>A p.L45I | Missense Mutation (SNP) | VAF 89/346 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.323); catalogued as COSV65841852; called by mutect2, varscan2
- OR52E1 | c.143T>C p.I48T | Missense Mutation (SNP) | VAF 100/380 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.92); catalogued as rs567699003; called by mutect2, varscan2
- PAPPA2 | c.800G>C p.G267A | Missense Mutation (SNP) | VAF 128/538 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV62783013; called by mutect2, varscan2
- PCDH17 | c.1834G>A p.A612T | Missense Mutation (SNP) | VAF 136/686 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64975650; called by mutect2, varscan2
- PCDHA7 | c.1094C>T p.P365L | Missense Mutation (SNP) | VAF 117/255 reads (46%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as rs1554134999, COSV65344200; called by mutect2, varscan2
- PGK2 | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 122/539 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.392); catalogued as COSV59163254; called by mutect2, varscan2
- PPIL2 | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 376/522 reads (72%) | SIFT tolerated (0.06); PolyPhen benign (0.313); catalogued as rs376001677; called by mutect2, varscan2
- RAP1GAP | c.1758C>A p.D586E | Missense Mutation (SNP) | VAF 69/407 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99265503; called by mutect2, varscan2
- RBMXL3 | c.2234G>A p.G745D | Missense Mutation (SNP) | VAF 160/479 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as rs782462330, COSV100407609; called by mutect2, varscan2
- REX1BD | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 154/544 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs759499673; called by mutect2, varscan2
- RICTOR | c.1446G>A p.M482I | Missense Mutation (SNP) | VAF 60/326 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.054); catalogued as COSV57121325; called by mutect2, varscan2
- RIMS2 | c.4388T>G p.L1463R (on ENST00000666250 / NM_001348490.2; = p.L1034R on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 90/381 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51650054; called by mutect2, varscan2
- SALL4 | c.1951G>A p.G651S | Missense Mutation (SNP) | VAF 150/483 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763359245, COSV53855331, COSV53856874; called by mutect2, varscan2
- SGSM2 | c.614A>G p.H205R | Missense Mutation (SNP) | VAF 158/517 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52156288; called by mutect2, varscan2
- SLC14A2 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 124/269 reads (46%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs758035710, COSV54907104; called by mutect2, varscan2
- SLITRK2 | c.503A>C p.N168T | Missense Mutation (SNP) | VAF 146/388 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59425466; called by mutect2, varscan2
- SPATA5 | c.2374A>G p.I792V | Missense Mutation (SNP) | VAF 30/258 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.031); catalogued as rs753188504; called by mutect2, varscan2
- TTN | c.6593C>T p.T2198I (on ENST00000591111; = p.T2152I on NM_003319.4) | Missense Mutation (SNP) | VAF 88/273 reads (32%) | PolyPhen possibly damaging (0.805); catalogued as rs886038879; ClinVar: uncertain significance; called by mutect2, varscan2
- UGT2B15 | c.1058G>C p.R353P | Missense Mutation (SNP) | VAF 59/410 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV57734876; called by mutect2, varscan2
- UGT3A2 | c.1214A>C p.K405T | Missense Mutation (SNP) | VAF 134/564 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.031); catalogued as rs1413936453, COSV104390750, COSV56930328; called by mutect2, varscan2
- ZNF213 | c.569C>T p.T190M | Missense Mutation (SNP) | VAF 129/553 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs912660666; called by mutect2, varscan2
- ZNF276 | c.1447C>T p.Q483* (on ENST00000443381 / NM_001113525.2; = p.Q408* on NM_152287.4) | Nonsense Mutation (SNP) | VAF 70/298 reads (23%) | catalogued as rs1413544686; called by mutect2, varscan2
- ZNF513 | c.811C>A p.L271I | Missense Mutation (SNP) | VAF 110/474 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.206); catalogued as COSV99277295; called by mutect2, varscan2
- ZNF613 | c.1110G>T p.K370N (on ENST00000293471 / NM_001031721.4; = p.K334N on NM_024840.4) | Missense Mutation (SNP) | VAF 121/616 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs376489157; called by mutect2, varscan2
- ABCC1 | c.3789G>T p.R1263S | Missense Mutation (SNP) | VAF 154/554 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); called by mutect2, varscan2
- ABCC2 | c.593C>A p.A198D | Missense Mutation (SNP) | VAF 69/286 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- ABTB2 | c.906C>A p.Y302* | Nonsense Mutation (SNP) | VAF 113/489 reads (23%) | called by mutect2, varscan2
- ACAD11 | c.55A>T p.K19* | Nonsense Mutation (SNP) | VAF 171/414 reads (41%) | called by mutect2, varscan2
- ADIPOR2 | c.845T>C p.F282S | Missense Mutation (SNP) | VAF 74/294 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- AFF1 | c.356_368del p.P119Hfs*37 | Frame Shift Del (DEL) | VAF 129/471 reads (27%) | called by mutect2, pindel*, varscan2
- AJM1 | c.601A>G p.T201A | Missense Mutation (SNP) | VAF 114/813 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by mutect2, varscan2
- ALPK3 | c.3392A>G p.E1131G | Missense Mutation (SNP) | VAF 142/613 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by mutect2, varscan2
- ARFGEF2 | c.5207A>G p.Y1736C | Missense Mutation (SNP) | VAF 78/252 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by mutect2, varscan2
- ARHGEF17 | c.3487G>A p.A1163T | Missense Mutation (SNP) | VAF 82/301 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); called by mutect2, varscan2
- ASXL1 | c.3570G>T p.R1190S | Missense Mutation (SNP) | VAF 112/456 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.012); called by mutect2, varscan2
- ATG2A | c.431C>G p.S144C | Missense Mutation (SNP) | VAF 132/615 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by mutect2, varscan2
- ATG9B | c.544C>A p.L182I | Missense Mutation (SNP) | VAF 89/550 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.258); called by mutect2, varscan2
- BACH2 | c.272T>A p.L91* | Nonsense Mutation (SNP) | VAF 226/417 reads (54%) | called by mutect2, varscan2
- BAHCC1 | c.113A>T p.Q38L | Missense Mutation (SNP) | VAF 146/546 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); called by mutect2, varscan2
- BCL9 | c.2524G>A p.G842R | Missense Mutation (SNP) | VAF 166/696 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by mutect2, varscan2
- C12orf43 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 74/249 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.359); called by mutect2, varscan2
- C12orf56 | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 67/171 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.022); called by mutect2, varscan2
- C8B | c.1315G>C p.A439P | Missense Mutation (SNP) | VAF 112/389 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by mutect2, varscan2
- CADM4 | c.98C>G p.T33R | Missense Mutation (SNP) | VAF 212/565 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- CASP14 | c.248T>C p.F83S | Missense Mutation (SNP) | VAF 114/364 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- CCDC158 | c.2113C>A p.Q705K | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); called by mutect2, varscan2
- CD1A | c.934C>A p.L312I | Missense Mutation (SNP) | VAF 131/506 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.012); called by mutect2, varscan2
- CD8B | c.103A>C p.K35Q | Missense Mutation (SNP) | VAF 190/595 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.005); called by mutect2, varscan2
- CES5A | c.893A>C p.K298T | Missense Mutation (SNP) | VAF 104/485 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.192); called by mutect2, varscan2
- CFDP1 | c.505_520del p.F169Kfs*3 | Frame Shift Del (DEL) | VAF 20/220 reads (9%) | called by mutect2, pindel
- CFH | c.327A>C p.K109N | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by mutect2, varscan2
- CNOT1 | c.808A>G p.I270V | Missense Mutation (SNP) | VAF 138/288 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); called by mutect2, varscan2
- COL10A1 | c.608G>T p.G203V | Missense Mutation (SNP) | VAF 82/328 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- COL11A2 | c.3559C>G p.P1187A (on ENST00000341947 / NM_080680.3; = p.P1080A on NM_080679.2) | Missense Mutation (SNP) | VAF 164/528 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); called by mutect2, varscan2
- COL16A1 | c.3175G>C p.V1059L | Missense Mutation (SNP) | VAF 144/442 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.388); called by mutect2, varscan2
- COL20A1 | c.1337_1358del p.V446Gfs*10 | Frame Shift Del (DEL) | VAF 88/455 reads (19%) | called by mutect2, pindel, varscan2
- CSNK2A1 | c.225G>T p.K75N | Missense Mutation (SNP) | VAF 52/372 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); called by mutect2, varscan2
- CSPP1 | c.3461C>T p.A1154V (on ENST00000676605; = p.A1113V on NM_024790.6) | Missense Mutation (SNP) | VAF 62/474 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.51); called by mutect2, varscan2
- CTAGE1 | c.1078C>G p.Q360E | Missense Mutation (SNP) | VAF 73/438 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.261); called by mutect2, varscan2
- DAG1 | c.1832A>G p.K611R | Missense Mutation (SNP) | VAF 194/370 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.001); called by mutect2, varscan2
- DCDC1 | c.3327G>T p.K1109N (on ENST00000597505 / NM_001367979.1; = p.K216N on NM_020869.3) | Missense Mutation (SNP) | VAF 96/423 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.299); called by mutect2, varscan2
- DDX3X | c.1375_1393del p.F459Tfs*30 (on ENST00000399959; = p.F460Tfs*30 on NM_001356.5) | Frame Shift Del (DEL) | VAF 109/347 reads (31%) | called by mutect2, pindel, varscan2
- DHX9 | c.2511A>C p.R837S | Missense Mutation (SNP) | VAF 82/268 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); called by mutect2, varscan2
- DLG3 | c.2320G>T p.E774* (on ENST00000374360 / NM_021120.4; = p.E469* on NM_020730.3) | Nonsense Mutation (SNP) | VAF 42/189 reads (22%) | called by mutect2, varscan2
- DMD | c.7924G>A p.D2642N | Missense Mutation (SNP) | VAF 98/303 reads (32%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.815); called by mutect2, varscan2
- DPP9 | c.1268T>A p.V423D (on ENST00000598800; = p.V452D on NM_139159.5) | Missense Mutation (SNP) | VAF 156/510 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by mutect2, varscan2
- EDRF1 | c.719C>G p.S240W | Missense Mutation (SNP) | VAF 133/360 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.441); called by mutect2, varscan2
- EHMT2 | c.1984G>A p.E662K | Missense Mutation (SNP) | VAF 144/467 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by mutect2, varscan2
- EMILIN1 | c.1618G>C p.G540R | Missense Mutation (SNP) | VAF 140/655 reads (21%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.862); called by mutect2, varscan2
- EPB41L2 | c.2042G>T p.G681V | Missense Mutation (SNP) | VAF 63/170 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.548); called by mutect2, varscan2
- ERVV-1 | c.1135_1144del p.N379* | Frame Shift Del (DEL) | VAF 127/729 reads (17%) | called by mutect2, pindel, varscan2
- FAM161A | c.176G>C p.G59A | Missense Mutation (SNP) | VAF 76/356 reads (21%) | SIFT tolerated (0.8); PolyPhen benign (0.039); called by mutect2, varscan2
- FBXO4 | c.69_71delinsC p.E24Gfs*30 | Frame Shift Del (DEL) | VAF 169/737 reads (23%) | called by pindel, varscan2*
- FEM1A | c.511G>C p.E171Q | Missense Mutation (SNP) | VAF 136/1123 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.088); called by mutect2, varscan2
- FHDC1 | c.1642G>A p.D548N | Missense Mutation (SNP) | VAF 170/346 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by mutect2, varscan2
- FOXQ1 | c.317G>A p.G106D | Missense Mutation (SNP) | VAF 170/654 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.091); called by mutect2, varscan2
- FSCB | c.951_957del p.Q317Hfs*8 | Frame Shift Del (DEL) | VAF 111/373 reads (30%) | called by mutect2, pindel, varscan2
- FSHR | c.1376C>A p.T459N | Missense Mutation (SNP) | VAF 44/458 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- GALNT2 | c.524A>T p.D175V | Missense Mutation (SNP) | VAF 80/446 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- GAS6 | c.1130G>A p.G377D | Missense Mutation (SNP) | VAF 74/423 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- GDF9 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 107/222 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.043); called by mutect2, varscan2
- GEM | c.622G>C p.A208P | Missense Mutation (SNP) | VAF 76/600 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); called by mutect2, varscan2
- GFRAL | c.443T>C p.L148S | Missense Mutation (SNP) | VAF 88/410 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- GOLGA3 | c.140A>T p.E47V | Missense Mutation (SNP) | VAF 98/314 reads (31%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.037); called by mutect2, varscan2
- GPD1L | c.53C>G p.S18* | Nonsense Mutation (SNP) | VAF 57/240 reads (24%) | called by mutect2, varscan2
- GSDMA | c.473A>T p.E158V | Missense Mutation (SNP) | VAF 208/445 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by mutect2, varscan2
- GTF3C4 | c.1561G>C p.A521P | Missense Mutation (SNP) | VAF 205/422 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- GUCY2C | c.2690C>T p.A897V | Missense Mutation (SNP) | VAF 232/466 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- GUCY2C | c.2689G>T p.A897S | Missense Mutation (SNP) | VAF 232/468 reads (50%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.98); called by mutect2, varscan2
- HOXA10 | c.14A>T p.K5M | Missense Mutation (SNP) | VAF 76/276 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- IFT81 | c.1539G>T p.Q513H | Missense Mutation (SNP) | VAF 44/144 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by mutect2, varscan2
- IL2RB | c.580T>C p.C194R | Missense Mutation (SNP) | VAF 243/384 reads (63%) | SIFT tolerated (0.32); PolyPhen benign (0.155); called by mutect2, varscan2
- INTS1 | c.6056A>G p.D2019G | Missense Mutation (SNP) | VAF 141/431 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by mutect2, varscan2
- ITGA5 | c.925T>C p.S309P | Missense Mutation (SNP) | VAF 120/402 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.68); called by mutect2, varscan2
- KEL | c.1558G>C p.V520L | Missense Mutation (SNP) | VAF 165/492 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by mutect2, varscan2
- KLHL9 | c.197A>G p.H66R | Missense Mutation (SNP) | VAF 225/349 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by mutect2, varscan2
- KPNA4 | c.677A>C p.N226T | Missense Mutation (SNP) | VAF 29/221 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by mutect2, varscan2
- LHX6 | c.772C>T p.L258F (on ENST00000373755 / NM_001242334.2; = p.L287F on NM_014368.5) | Missense Mutation (SNP) | VAF 166/549 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- MAMLD1 | c.1734_1743del p.T579Pfs*36 | Frame Shift Del (DEL) | VAF 154/502 reads (31%) | called by mutect2, pindel, varscan2
- MNS1 | c.1406A>T p.K469I | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by mutect2, varscan2
- MORC2 | c.1826G>T p.R609I (on ENST00000397641 / NM_001303256.3; = p.R547I on NM_014941.3) | Missense Mutation (SNP) | VAF 86/280 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.416); called by mutect2, varscan2
- MSANTD2 | c.1478T>C p.F493S (on ENST00000374979 / NM_001308027.2; = p.F441S on NM_024631.4) | Missense Mutation (SNP) | VAF 95/330 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- MSS51 | c.742C>G p.L248V | Missense Mutation (SNP) | VAF 180/484 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.01); called by mutect2, varscan2
- MTMR7 | c.272A>T p.H91L | Missense Mutation (SNP) | VAF 216/322 reads (67%) | SIFT tolerated (0.1); PolyPhen benign (0.013); called by mutect2, varscan2
- MUC16 | c.6890G>T p.S2297I | Missense Mutation (SNP) | VAF 94/353 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.071); called by mutect2, varscan2
- MYDGF | c.154T>G p.S52A | Missense Mutation (SNP) | VAF 141/940 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); called by mutect2, varscan2
- N4BP1 | c.869C>G p.S290C | Missense Mutation (SNP) | VAF 79/358 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); called by mutect2, varscan2
- NALCN | c.4271T>A p.L1424H | Missense Mutation (SNP) | VAF 64/330 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by mutect2, varscan2
- NARS2 | c.344T>A p.I115N | Missense Mutation (SNP) | VAF 52/166 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by mutect2, varscan2
- NETO1 | c.574G>A p.G192S | Missense Mutation (SNP) | VAF 82/266 reads (31%) | SIFT tolerated (0.58); PolyPhen benign (0.16); called by mutect2, varscan2
- NIPBL | c.4341A>T p.K1447N | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.569); called by mutect2, varscan2
- NOVA1 | c.126del p.N43Ifs*10 | Frame Shift Del (DEL) | VAF 108/486 reads (22%) | called by mutect2, pindel, varscan2
- NPHP1 | c.1346T>G p.L449W (on ENST00000393272 / NM_207181.4; = p.L450W on NM_000272.5) | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by mutect2, varscan2
- NPHP1 | c.1131A>T p.R377S (on ENST00000393272 / NM_207181.4; = p.R378S on NM_000272.5) | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.448); called by mutect2, varscan2
- NUGGC | c.2065G>A p.A689T | Missense Mutation (SNP) | VAF 132/462 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by mutect2, varscan2
- NXPE4 | c.1333G>C p.D445H (on ENST00000375478 / NM_001077639.2; = p.D161H on NM_017678.3) | Missense Mutation (SNP) | VAF 136/356 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.071); called by mutect2, varscan2
- OGFRL1 | c.1168A>T p.K390* | Nonsense Mutation (SNP) | VAF 102/323 reads (32%) | called by mutect2, varscan2
- OLFM1 | c.1270G>A p.V424I (on ENST00000371793 / NM_001282611.2; = p.V406I on NM_014279.5) | Missense Mutation (SNP) | VAF 124/614 reads (20%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.992); called by mutect2, varscan2
- OR1E2 | c.956del p.N319Ifs*? | Frame Shift Del (DEL) | VAF 48/208 reads (23%) | called by mutect2, pindel, varscan2
- OR2T33 | c.887A>C p.K296T | Missense Mutation (SNP) | VAF 110/518 reads (21%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.821); called by mutect2, varscan2
- OTOF | c.4919A>T p.N1640I (on ENST00000272371 / NM_194248.3; = p.N873I on NM_004802.4) | Missense Mutation (SNP) | VAF 163/566 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by mutect2, varscan2
- PCDHB13 | c.1625G>A p.S542N | Missense Mutation (SNP) | VAF 216/497 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.651); called by mutect2, varscan2
- PCDHB13 | c.1626C>G p.S542R | Missense Mutation (SNP) | VAF 214/496 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.873); called by mutect2, varscan2
- PCNT | c.8213G>T p.S2738I | Missense Mutation (SNP) | VAF 140/429 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.125); called by mutect2, varscan2
- PDCL2 | c.659C>T p.S220F | Missense Mutation (SNP) | VAF 54/261 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.845); called by mutect2, varscan2
- PDE5A | c.2521C>A p.P841T | Missense Mutation (SNP) | VAF 80/165 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by mutect2, varscan2
- PLCL2 | c.910A>G p.K304E (on ENST00000615277 / NM_001144382.2; = p.K178E on NM_015184.5) | Missense Mutation (SNP) | VAF 89/351 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.573); called by mutect2, varscan2
- PLD4 | c.1400A>G p.Q467R | Missense Mutation (SNP) | VAF 158/296 reads (53%) | SIFT tolerated (0.31); PolyPhen benign (0); called by mutect2, varscan2
- PPP1R14A | c.391C>G p.H131D | Missense Mutation (SNP) | VAF 169/916 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by mutect2, varscan2
- PRRC2B | c.4814del p.K1605Sfs*12 | Frame Shift Del (DEL) | VAF 76/446 reads (17%) | called by pindel, varscan2
- RAD54B | c.2083C>A p.P695T | Missense Mutation (SNP) | VAF 78/570 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); called by mutect2, varscan2
- RBM26 | c.251C>T p.P84L | Missense Mutation (SNP) | VAF 74/310 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.202); called by mutect2, varscan2
- RGS6 | c.931A>C p.S311R | Missense Mutation (SNP) | VAF 68/158 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by mutect2, varscan2
- RICTOR | c.4880T>C p.V1627A | Missense Mutation (SNP) | VAF 48/164 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.98); called by mutect2, varscan2
- RPTOR | c.3947T>G p.L1316R | Missense Mutation (SNP) | VAF 146/358 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by mutect2, varscan2
- SACS | c.7280T>C p.I2427T | Missense Mutation (SNP) | VAF 74/277 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.165); called by mutect2, varscan2
- SBF2 | c.4143G>C p.E1381D | Missense Mutation (SNP) | VAF 83/273 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by mutect2, varscan2
- SBNO2 | c.2522_2566del p.T841_L855del | In Frame Del (DEL) | VAF 90/748 reads (12%) | called by mutect2, pindel
- SDK2 | c.2392G>A p.V798M | Missense Mutation (SNP) | VAF 77/346 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- SDR9C7 | c.83T>A p.V28D | Missense Mutation (SNP) | VAF 173/526 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- SDS | c.713A>T p.E238V | Missense Mutation (SNP) | VAF 126/369 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.035); called by mutect2, varscan2
- SEPTIN4 | c.1057G>C p.V353L | Missense Mutation (SNP) | VAF 123/488 reads (25%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.859); called by mutect2, varscan2
- SH3GL2 | c.988G>T p.G330W | Missense Mutation (SNP) | VAF 129/398 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- SHQ1 | c.43C>G p.L15V | Missense Mutation (SNP) | VAF 96/314 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- SLC22A3 | c.697del p.I233* | Frame Shift Del (DEL) | VAF 128/243 reads (53%) | called by mutect2, pindel, varscan2
- SLC38A10 | c.2248G>A p.V750M | Missense Mutation (SNP) | VAF 97/374 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0.012); called by mutect2, varscan2
- SPTA1 | c.4064T>G p.L1355R | Missense Mutation (SNP) | VAF 108/450 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by mutect2, varscan2
- SRPK2 | c.1838_1860del p.F613Sfs*23 | Frame Shift Del (DEL) | VAF 79/359 reads (22%) | called by mutect2, pindel, varscan2
- TAX1BP1 | c.449T>A p.L150H | Missense Mutation (SNP) | VAF 76/223 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by mutect2, varscan2
- TEFM | c.166G>C p.E56Q | Missense Mutation (SNP) | VAF 94/512 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.01); called by mutect2, varscan2
- TEP1 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 76/376 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by mutect2, varscan2
- TGFBRAP1 | c.2405A>T p.K802M | Missense Mutation (SNP) | VAF 72/190 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.667); called by mutect2, varscan2
- TIAM1 | c.1877C>G p.A626G | Missense Mutation (SNP) | VAF 96/318 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.105); called by mutect2, varscan2
- TLR7 | c.2578A>C p.S860R | Missense Mutation (SNP) | VAF 142/212 reads (67%) | SIFT tolerated (0.21); PolyPhen benign (0.14); called by mutect2, varscan2
- TREH | c.1197G>C p.W399C | Missense Mutation (SNP) | VAF 60/410 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by mutect2, varscan2
- TRGC1 | c.443A>C p.K148T | Missense Mutation (SNP) | VAF 120/434 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.523); called by mutect2, varscan2
- TTN | c.55790A>C p.K18597T (on ENST00000591111; = p.K11173T on NM_003319.4) | Missense Mutation (SNP) | VAF 136/389 reads (35%) | PolyPhen possibly damaging (0.866); called by mutect2, varscan2
- TUBB4B | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 91/422 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.552); called by mutect2, varscan2
- UBA2 | c.1504A>T p.N502Y | Missense Mutation (SNP) | VAF 58/306 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.179); called by mutect2, varscan2
- UFL1 | c.1910A>T p.D637V | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.074); called by mutect2, varscan2
- UGT2A1 | c.1058A>G p.D353G | Missense Mutation (SNP) | VAF 60/189 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- UNC13C | c.5428_5439del p.K1810_E1813del | In Frame Del (DEL) | VAF 27/99 reads (27%) | called by mutect2, pindel, varscan2
- USP17L7 | c.1447C>G p.Q483E | Missense Mutation (SNP) | VAF 148/394 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); called by mutect2, varscan2
- USP24 | c.2323_2340del p.K775_E780del | In Frame Del (DEL) | VAF 26/120 reads (22%) | called by mutect2, pindel, varscan2
- USP27X | c.380_400del p.S127_L133del | In Frame Del (DEL) | VAF 126/437 reads (29%) | called by mutect2, pindel, varscan2
- USP35 | c.2901G>C p.K967N | Missense Mutation (SNP) | VAF 108/349 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.879); called by mutect2, varscan2
- UTP6 | c.715C>T p.H239Y | Missense Mutation (SNP) | VAF 72/334 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.073); called by mutect2, varscan2
- VANGL1 | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 152/432 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); called by mutect2, varscan2
- VPS8 | c.1987A>G p.S663G (on ENST00000625842 / NM_001349294.1; = p.S661G on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); called by mutect2, varscan2
- VWF | c.8339A>C p.E2780A | Missense Mutation (SNP) | VAF 123/463 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by mutect2, varscan2
- WNT8A | c.494_496del p.N165del | In Frame Del (DEL) | VAF 92/218 reads (42%) | called by pindel, varscan2
- ZBTB32 | c.985A>G p.S329G | Missense Mutation (SNP) | VAF 129/783 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.412); called by mutect2, varscan2
- ZNF468 | c.1226A>C p.K409T | Missense Mutation (SNP) | VAF 63/400 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by mutect2, varscan2
- ZNF557 | c.635G>A p.S212N (on ENST00000414706 / NM_001044388.2; = p.S219N on NM_024341.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/302 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.249); called by mutect2, varscan2
- ZNF630 | c.674A>C p.E225A | Missense Mutation (SNP) | VAF 122/328 reads (37%) | SIFT tolerated (0.59); PolyPhen benign (0.089); called by mutect2, varscan2
- ABCC2 | c.940C>T p.L314= | Silent (SNP) | VAF 80/342 reads (23%) | catalogued as COSV64971394; called by mutect2, varscan2
- ACTRT2 | c.309C>T p.S103= | Silent (SNP) | VAF 170/583 reads (29%) | catalogued as rs755066337; called by mutect2, varscan2
- ADAMTSL3 | c.2976G>T p.V992= | Silent (SNP) | VAF 108/322 reads (34%) | called by mutect2, varscan2
- ANKRD30B | c.3498A>G p.Q1166= | Silent (SNP) | VAF 28/84 reads (33%) | called by mutect2, varscan2
- APBA1 | c.582G>A p.Q194= | Silent (SNP) | VAF 144/466 reads (31%) | catalogued as COSV55225899; called by mutect2, varscan2
- ASTN1 | c.1071C>T p.P357= | Silent (SNP) | VAF 88/395 reads (22%) | catalogued as rs1320540165; called by mutect2, varscan2
- BRSK2 | c.111T>C p.V37= | Silent (SNP) | VAF 90/242 reads (37%) | called by mutect2, varscan2
- CCNP | c.786C>G p.L262= | Silent (SNP) | VAF 153/907 reads (17%) | called by mutect2, varscan2
- DAPK1 | c.1875G>C p.V625= | Silent (SNP) | VAF 106/382 reads (28%) | called by mutect2, varscan2
- DCST2 | c.798C>T p.I266= | Silent (SNP) | VAF 103/487 reads (21%) | catalogued as rs915404709; called by mutect2, varscan2
- DOCK3 | c.3048C>T p.S1016= | Silent (SNP) | VAF 70/167 reads (42%) | catalogued as rs1336443164; called by mutect2, varscan2
- DSP | c.8040T>A p.I2680= | Silent (SNP) | VAF 216/445 reads (49%) | called by mutect2, varscan2
- DTHD1 | c.537T>C p.V179= (on ENST00000456874; = p.V14= on NM_001136536.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 60/222 reads (27%) | catalogued as rs1377817184; called by mutect2, varscan2
- DZANK1 | c.1005G>A p.G335= (on ENST00000262547 / NM_001099407.1; = p.G136= on NM_018152.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 110/432 reads (25%) | catalogued as rs765344502; called by mutect2, varscan2
- EEPD1 | c.810C>G p.G270= | Silent (SNP) | VAF 140/408 reads (34%) | called by mutect2, varscan2
- ELFN1 | c.753C>T p.T251= | Silent (SNP) | VAF 221/716 reads (31%) | catalogued as rs774207674; called by mutect2, varscan2
- FAM181B | c.1056C>G p.P352= | Silent (SNP) | VAF 186/556 reads (33%) | called by mutect2, varscan2
- FERMT1 | c.1197A>G p.T399= | Silent (SNP) | VAF 42/202 reads (21%) | called by mutect2, varscan2
- FMO5 | c.156G>A p.R52= | Silent (SNP) | VAF 36/144 reads (25%) | catalogued as rs782325426; called by mutect2, varscan2
- GALK1 | c.826C>A p.R276= | Silent (SNP) | VAF 60/461 reads (13%) | called by mutect2, varscan2
- GLI3 | c.4104C>T p.H1368= | Silent (SNP) | VAF 140/472 reads (30%) | catalogued as rs780530149, COSV101229683; called by mutect2, varscan2
- HOXC10 | c.63A>C p.G21= | Silent (SNP) | VAF 138/520 reads (27%) | called by mutect2, varscan2
- IGSF21 | c.1371G>C p.V457= | Silent (SNP) | VAF 110/352 reads (31%) | called by mutect2, varscan2
- JMJD4 | c.237C>T p.V79= | Silent (SNP) | VAF 162/832 reads (19%) | catalogued as COSV59917302; called by mutect2, varscan2
- KRT75 | c.1065A>G p.R355= | Silent (SNP) | VAF 71/246 reads (29%) | called by mutect2, varscan2
- LTF | c.771A>G p.P257= | Silent (SNP) | VAF 272/427 reads (64%) | called by mutect2, varscan2
- MKKS | c.1176G>C p.T392= | Silent (SNP) | VAF 50/247 reads (20%) | catalogued as COSV61400022; called by mutect2, varscan2
- MUC2 | c.4098G>A p.K1366= | Silent (SNP) | VAF 93/362 reads (26%) | called by mutect2, varscan2
- MYH14 | c.4281A>G p.E1427= | Silent (SNP) | VAF 310/768 reads (40%) | called by mutect2, varscan2
- NCAM1 | c.1263T>A p.P421= (on ENST00000316851 / NM_181351.5; = p.P411= on NM_000615.7) | Silent (SNP) | VAF 78/276 reads (28%) | called by mutect2, varscan2
- NKPD1 | c.1362G>T p.V454= | Silent (SNP) | VAF 136/653 reads (21%) | called by mutect2, varscan2
- NPC1 | c.3792A>G p.E1264= | Silent (SNP) | VAF 99/900 reads (11%) | catalogued as rs1210213899; called by mutect2, varscan2
- ODF3 | c.526C>T p.L176= | Silent (SNP) | VAF 76/314 reads (24%) | catalogued as COSV57294007; called by mutect2, varscan2
- OR2M3 | c.99C>G p.A33= | Silent (SNP) | VAF 109/620 reads (18%) | catalogued as COSV101513394; called by mutect2, varscan2
- OR4D11 | c.348T>C p.S116= | Silent (SNP) | VAF 90/384 reads (23%) | called by mutect2, varscan2
- OR51A4 | c.462C>T p.S154= | Silent (SNP) | VAF 112/404 reads (28%) | called by mutect2, varscan2
- OXCT1 | c.147T>C p.A49= | Silent (SNP) | VAF 95/257 reads (37%) | catalogued as COSV52173373; called by mutect2, varscan2
- PCDHA3 | c.459G>T p.S153= | Silent (SNP) | VAF 110/241 reads (46%) | catalogued as rs370475459, COSV65365170; called by mutect2, varscan2
- PEX1 | c.168A>G p.A56= | Silent (SNP) | VAF 156/270 reads (58%) | called by mutect2, varscan2
- PHLDB1 | c.2661G>C p.L887= | Silent (SNP) | VAF 84/322 reads (26%) | catalogued as rs1555118118; called by mutect2, varscan2
- PKD1L2 | c.2223G>A p.L741= | Silent (SNP) | VAF 89/397 reads (22%) | called by mutect2, varscan2
- PKDREJ | c.1377C>T p.H459= | Silent (SNP) | VAF 306/424 reads (72%) | called by mutect2, varscan2
- PLCB1 | c.1197A>T p.A399= | Silent (SNP) | VAF 65/315 reads (21%) | called by mutect2, varscan2
- POLD1 | c.366G>A p.V122= | Silent (SNP) | VAF 138/734 reads (19%) | called by mutect2, varscan2
- PRDM16 | c.2820C>G p.S940= | Silent (SNP) | VAF 116/394 reads (29%) | catalogued as COSV99579485; called by mutect2, varscan2
- PRRC2B | c.6273C>T p.I2091= | Silent (SNP) | VAF 124/541 reads (23%) | catalogued as rs753414635; called by mutect2, varscan2
- PTPN14 | c.1626G>T p.L542= | Silent (SNP) | VAF 133/720 reads (18%) | called by mutect2, varscan2
- RAPGEF6 | c.3774T>G p.S1258= | Silent (SNP) | VAF 84/162 reads (52%) | called by mutect2, varscan2
- REXO1 | c.54G>C p.G18= | Silent (SNP) | VAF 88/244 reads (36%) | called by mutect2, varscan2
- RPS4Y1 | c.712C>T p.L238= | Silent (SNP) | VAF 74/149 reads (50%) | called by mutect2, varscan2
- SBNO1 | c.3936G>T p.L1312= (on ENST00000420886; = p.L1311= on NM_018183.5) | Silent (SNP) | VAF 92/354 reads (26%) | called by mutect2, varscan2
- SLC12A1 | c.33G>A p.L11= | Silent (SNP) | VAF 33/137 reads (24%) | called by mutect2, varscan2
- SLIT2 | c.171C>T p.T57= | Silent (SNP) | VAF 106/604 reads (18%) | catalogued as rs774811823, COSV56579793, COSV56590120; called by mutect2, varscan2
- SPDYE3 | c.42C>T p.P14= | Silent (SNP) | VAF 50/161 reads (31%) | called by mutect2, varscan2
- TSHZ3 | c.525G>A p.T175= | Silent (SNP) | VAF 300/1369 reads (22%) | catalogued as rs368807538; called by mutect2, varscan2
- TSPAN4 | c.252C>G p.L84= | Silent (SNP) | VAF 69/261 reads (26%) | called by mutect2, varscan2
- TUBGCP6 | c.945G>A p.A315= | Silent (SNP) | VAF 214/342 reads (63%) | catalogued as rs144685624; called by mutect2, varscan2
- TXLNB | c.2016G>A p.P672= | Silent (SNP) | VAF 82/302 reads (27%) | catalogued as rs1310844778; called by mutect2, varscan2
- UNC93A | c.1299C>T p.S433= | Silent (SNP) | VAF 128/600 reads (21%) | called by mutect2, varscan2
- UPK1A | c.144A>G p.V48= | Silent (SNP) | VAF 116/650 reads (18%) | catalogued as rs763145673, COSV99721825; called by mutect2, varscan2
- USP15 | c.1545A>T p.I515= (on ENST00000280377 / NM_001351159.2; = p.I486= on NM_006313.3 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 32/154 reads (21%) | called by mutect2, varscan2
- XKR6 | c.1551C>G p.L517= | Silent (SNP) | VAF 266/406 reads (66%) | catalogued as rs367810172; called by mutect2, varscan2
- ZNF225 | c.1230T>C p.Y410= | Silent (SNP) | VAF 130/655 reads (20%) | called by mutect2, varscan2
- ZNF385B | c.513T>G p.V171= | Silent (SNP) | VAF 98/149 reads (66%) | called by mutect2, varscan2
- C2orf16 | chr2:27572724 A>C | 5'Flank (SNP) | VAF 123/379 reads (32%) | called by mutect2, varscan2
- COL6A5 | c.-86T>C | 5'UTR (SNP) | VAF 122/538 reads (23%) | called by mutect2, varscan2
- GCSH | chr16:81101272 C>T | 5'Flank (SNP) | VAF 68/276 reads (25%) | catalogued as rs1468222230; called by mutect2, varscan2
- KCNQ1 | c.1514+1608C>T | Intron (SNP) | VAF 134/358 reads (37%) | called by mutect2, varscan2
- MYC | c.-185C>A | 5'UTR (SNP) | VAF 140/1248 reads (11%) | catalogued as COSV104388470; called by mutect2, varscan2
- NBR1 | c.*650G>C | 3'UTR (SNP) | VAF 256/412 reads (62%) | called by mutect2, varscan2
- NEDD4L | c.297+4294C>T | Intron (SNP) | VAF 154/403 reads (38%) | called by mutect2, varscan2
- PDE4C | c.243-4043G>T | Intron (SNP) | VAF 153/479 reads (32%) | called by mutect2, varscan2
- PDE4DIP | c.637-7229G>A | Intron (SNP) | VAF 80/726 reads (11%) | called by mutect2, varscan2
- RGS3 | c.3081-508G>A | Intron (SNP) | VAF 173/372 reads (47%) | called by mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-23860A>G | Intron (SNP) | VAF 52/214 reads (24%) | called by mutect2, varscan2
- SLMAP | c.1337-1073C>A | Intron (SNP) | VAF 36/165 reads (22%) | called by mutect2, varscan2
- WDR86 | c.*244C>T | 3'UTR (SNP) | VAF 242/522 reads (46%) | called by mutect2, varscan2
- Z99774.2 | chr22:26674686 T>G | 3'Flank (SNP) | VAF 86/409 reads (21%) | called by mutect2, varscan2
